Gene-level copy-number profile of tumor specimen TCGA-66-2742-01A from TCGA case TCGA-66-2742, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 70.3 years (25,688 days).
Specimen TCGA-66-2742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.552910ee-d460-47c3-9db5-d7dfc006a435.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2742-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/795e9d24-937e-41bd-b77f-fc6859ff30fc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 407; copy number 2: 14,780; copy number 3: 24,053; copy number 4: 11,213; copy number 5: 3,786; copy number 6: 2,792; copy number 7: 674; copy number 8: 1,063; copy number 12: 973; copy number 17: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2742-01A-01D-0978-01): tumor purity 0.44, ploidy 3.32, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 52 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–24,088,051, 34 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1.
- chr11:128,458,761–129,538,114, 18 genes: ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,721 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,236,967–175,335,459, 886 genes, copy number 7–8 (broad region; genes not listed).
- chr1:176,857,302–186,988,981, 194 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr1:192,158,462–194,198,708, 30 genes, copy number 8: RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14.
- chr3:90,030,284–112,649,530, 253 genes, copy number 7–12 (broad region; genes not listed).
- chr3:127,689,062–198,222,513, 1,259 genes, copy number 7–17 (within-gene range 6–17) (broad region; genes not listed).
- chr19:14,091,688–15,332,545, 58 genes, copy number 7 (within-gene range 2–7): PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P, AC011509.3, AC011509.2, AC011509.1, LINC01841, LINC01842, ADGRE5, AC008569.1, DDX39A, PKN1, AC008569.2, PTGER1, GIPC1, SNRPGP15, DNAJB1, TECR, MIR639, NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P, OR7A3P, OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4.
- chr20:39,932,922–41,383,107, 21 genes, copy number 8: HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1.
- chr20:41,459,354–41,461,944, 1 gene, copy number 8: AL031667.2.
- chr20:46,540,946–47,412,327, 19 genes, copy number 8: OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754.

Autosomal genes at a single copy (total copy number 1): 407. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
